Somatic mutation profile of tumor specimen TCGA-CR-7371-01A (aliquot TCGA-CR-7371-01A-11D-2012-08) from TCGA case TCGA-CR-7371, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 45.4 years (16,568 days).
Specimen TCGA-CR-7371-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3634ec09-856d-490b-91c3-cec9c934e6d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7371-10A (Blood Derived Normal), aliquot TCGA-CR-7371-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60743a5e-ac55-46a5-96e4-c257e92838e1

The open-access MAF lists 312 somatic variants for this specimen: 231 protein-altering or splice-affecting, 75 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 188, Silent 75, Nonsense Mutation 20, Splice Site 12, Intron 5, Frame Shift Del 5, Splice Region 3, Frame Shift Ins 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AASDH | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as rs765349701, COSV52704659; called by muse, mutect2, varscan2
- ABCA2 | c.1603G>A p.E535K (on ENST00000614293; = p.E505K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99688401; called by muse, mutect2, varscan2
- ABCC8 | c.881C>A p.A294D | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV100217704, COSV56854747; called by muse, mutect2, varscan2
- ABCD4 | c.718A>T p.R240* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100084538; called by muse, mutect2, varscan2
- ABLIM1 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.305); catalogued as COSV100986630; called by muse, mutect2, varscan2
- ACTN2 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100856980; called by muse, mutect2, varscan2
- ADAM33 | c.275A>T p.Y92F | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.583); catalogued as COSV100598074; called by muse, mutect2, varscan2
- ADGRB3 | c.3100C>T p.L1034= | Splice Region (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99486768; called by muse, mutect2
- AGXT | c.777-1G>A p.X259_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as CS043118, COSV100280355; called by mutect2, varscan2
- AIF1L | c.278C>G p.S93* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as COSV99908321; called by muse, mutect2
- AKAP9 | c.11146G>C p.D3716H (on ENST00000359028; = p.D3692H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100663056; called by muse, mutect2, varscan2
- ALAD | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs980453242, COSV99475024; called by muse, mutect2, varscan2
- AMOT | c.2047C>G p.Q683E (on ENST00000371959 / NM_001113490.1; = p.Q274E on NM_133265.3) | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100495525; called by muse, mutect2, varscan2
- AP3M2 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.158); catalogued as COSV99441898; called by muse, mutect2, varscan2
- APOBEC2 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs760829942, COSV55142479; called by muse, mutect2
- ARAP3 | c.4390G>C p.E1464Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as COSV53353297, COSV99500242; called by muse, mutect2, varscan2
- ATP10D | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV99906159; called by muse, mutect2, varscan2
- ATP1B3 | c.164C>G p.S55* | Nonsense Mutation (SNP) | VAF 18/104 reads (17%) | catalogued as COSV53950279, COSV53950402; called by muse, mutect2, varscan2
- ATP2A2 | c.3084G>T p.W1028C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); catalogued as COSV100428885; called by muse, mutect2, varscan2
- ATP5MC3 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99507241; called by muse, mutect2, varscan2
- ATP8A2 | c.1976G>T p.R659L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV99684104; called by muse, mutect2, varscan2
- BIRC6 | c.4091C>T p.S1364L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as rs754429641, COSV101428830; called by mutect2, varscan2
- C12orf40 | c.904C>A p.Q302K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV100210744; called by muse, mutect2, varscan2
- C2orf78 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV101281030; called by muse, mutect2, varscan2
- C9orf135 | c.152+2T>A p.X51_splice | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV101019921; called by muse, mutect2, varscan2
- CALB2 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 15/79 reads (19%) | catalogued as COSV100226414; called by muse, mutect2, varscan2
- CASQ1 | c.68T>A p.L23Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.213); catalogued as COSV100927365; called by muse, mutect2, varscan2
- CCDC88C | c.2014C>T p.Q672* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV101106147; called by muse, mutect2
- CEP112 | c.1071A>T p.K357N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101211129; called by muse, mutect2
- CERK | c.818C>A p.S273* | Nonsense Mutation (SNP) | VAF 17/141 reads (12%) | catalogued as COSV99348594, COSV99348787; called by muse, mutect2, varscan2
- CFHR2 | c.386G>T p.C129F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100804214; called by muse, varscan2
- CHST8 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.251); catalogued as rs766265994, COSV52859278; called by muse, mutect2, varscan2
- CLCN4 | c.1151C>G p.A384G | Missense Mutation (SNP) | VAF 49/326 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV101074041; called by muse, mutect2, varscan2
- CLEC16A | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101278451; called by muse, mutect2, varscan2
- CLEC4E | c.214G>T p.G72* | Nonsense Mutation (SNP) | VAF 17/132 reads (13%) | catalogued as COSV100222741, COSV55226531; called by muse, mutect2, varscan2
- CLEC4M | c.370G>C p.G124R | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV99940823; called by muse, varscan2
- CLK2 | c.1-1G>C p.X1_splice | Splice Site (SNP) | VAF 17/173 reads (10%) | catalogued as COSV100751923; called by muse, mutect2, varscan2
- CNTN3 | c.1951G>T p.E651* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as COSV55161917, COSV99726007; called by muse, mutect2, varscan2
- CNTN3 | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99726008; called by muse, mutect2, varscan2
- COL14A1 | c.3955G>T p.V1319F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV52853589; called by muse, mutect2, varscan2
- COL22A1 | c.4185+1G>T p.X1395_splice | Splice Site (SNP) | VAF 21/86 reads (24%) | catalogued as COSV100280659; called by muse, mutect2, varscan2
- COL25A1 | c.1405C>G p.P469A | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV101211627, COSV101211628; called by muse, mutect2, varscan2
- COL28A1 | c.2842G>C p.E948Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101258922, COSV68084100; called by muse, mutect2, varscan2
- COL5A1 | c.4878A>T p.K1626N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100880559; called by muse, mutect2, varscan2
- CPB1 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51571695, COSV99294507; called by muse, mutect2, varscan2
- CPXM1 | c.1837G>T p.A613S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.264); catalogued as COSV101013829, COSV66045391, COSV66046457; called by muse, mutect2, varscan2
- CRB1 | c.2921C>A p.T974N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV66328981, COSV66333082; called by muse, mutect2, varscan2
- CSGALNACT2 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100989848, COSV65675061; called by muse, mutect2, varscan2
- CSMD1 | c.2341G>C p.D781H (on ENST00000520002; = p.D780H on NM_033225.6) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100153372; called by muse, mutect2, varscan2
- CSMD2 | c.5081-1G>A p.X1694_splice | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99594954; called by muse, mutect2
- CSNK2A2 | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99345446; called by muse, mutect2, varscan2
- CTNNA2 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as COSV100786054; called by muse, mutect2, varscan2
- DENND1A | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV101010782; called by muse, mutect2
- DGKA | c.395G>C p.S132T | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.348); catalogued as COSV100093406; called by muse, mutect2, varscan2
- DIPK1C | c.1153C>G p.P385A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV100679966; called by muse, mutect2, varscan2
- DMD | c.8680G>C p.E2894Q | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as CM098456, COSV100629178, COSV58919375; called by muse, mutect2, varscan2
- DOCK2 | c.4429G>C p.G1477R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99912895, COSV99915196; called by muse, mutect2, varscan2
- DPYD | c.1411A>T p.T471S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV100929372; called by muse, mutect2, varscan2
- DZANK1 | c.1374G>C p.Q458H (on ENST00000262547 / NM_001099407.1; = p.Q265H on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs1332017826, COSV99363190; called by muse, mutect2, varscan2
- EEA1 | c.1496G>T p.S499I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV100468468; called by muse, mutect2, varscan2
- F5 | c.2665A>T p.K889* | Nonsense Mutation (SNP) | VAF 30/170 reads (18%) | catalogued as COSV100889225; called by muse, mutect2, varscan2
- F5 | c.2664T>A p.H888Q | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV100889226; called by muse, mutect2, varscan2
- FAM214B | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs746651794, COSV100521442; called by muse, mutect2, varscan2
- FAM222A | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100734597; called by muse, mutect2, varscan2
- FBXL13 | c.368G>T p.R123M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV100502086; called by muse, mutect2, varscan2
- FEM1A | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.391); catalogued as COSV99521562; called by muse, mutect2, varscan2
- FLG | c.4318T>C p.S1440P | Missense Mutation (SNP) | VAF 15/305 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100911459, COSV100912116; called by muse, mutect2
- FLT3 | c.2587G>T p.G863C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99610111; called by muse, mutect2, varscan2
- FNDC5 | c.625C>A p.R209S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100992536, COSV65105788; called by muse, mutect2, varscan2
- FREM2 | c.6580G>C p.E2194Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.359); catalogued as COSV99750668; called by muse, mutect2, varscan2
- FRMD6 | c.1699C>G p.Q567E (on ENST00000344768 / NM_001267046.2; = p.Q559E on NM_152330.4) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100656289, COSV61088079; called by muse, mutect2, varscan2
- FRMPD4 | c.3403G>A p.D1135N | Missense Mutation (SNP) | VAF 40/343 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as COSV101044012; called by muse, mutect2, varscan2
- FRRS1L | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as rs778701306, COSV101643942; called by mutect2, varscan2
- FSCB | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100469827, COSV61216548; called by muse, varscan2
- FSCB | c.418T>A p.W140R | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV100469830; called by muse, varscan2
- FUT9 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV100134322, COSV56143911; called by muse, mutect2, varscan2
- FZR1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs1308640029, COSV100553840; called by muse, mutect2, varscan2
- GABRQ | c.975C>G p.I325M | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100941424; called by muse, mutect2, varscan2
- GPAT2 | c.1899C>T p.T633= | Splice Region (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100853353; called by muse, mutect2, varscan2
- GPLD1 | c.1384G>T p.D462Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100015582; called by muse, varscan2
- GPR142 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1340847032, COSV59519526; called by muse, varscan2
- GPRC5C | c.1427C>G p.S476C (on ENST00000652232; = p.S431C on NM_018653.4) | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.885); catalogued as rs1471262881, COSV61235121; called by muse, mutect2, varscan2
- GRAMD4 | c.283+1G>T p.X95_splice | Splice Site (SNP) | VAF 35/140 reads (25%) | catalogued as COSV100730642, COSV63030847; called by muse, mutect2, varscan2
- GRID2 | c.2710C>G p.P904A | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.956); catalogued as COSV99946388; called by muse, mutect2
- GRIN2B | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101663179; called by muse, mutect2, varscan2
- H4C11 | c.185T>C p.F62S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100748019; called by muse, mutect2, varscan2
- H4C12 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100694725, COSV100694774; called by mutect2, varscan2
- HARBI1 | c.437G>C p.G146A | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100366010; called by muse, mutect2, varscan2
- HIC2 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as COSV101335633; called by muse, mutect2, varscan2
- HOOK3 | c.1863A>T p.K621N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100295977; called by muse, mutect2, varscan2
- HSPA8 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.047); catalogued as COSV99914612; called by muse, mutect2, varscan2
- HSPG2 | c.11563-1G>C p.X3855_splice | Splice Site (SNP) | VAF 3/21 reads (14%) | catalogued as COSV65933590; called by muse, mutect2
- IFI16 | c.1887C>G p.I629M (on ENST00000295809 / NM_001364867.2; = p.I573M on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99858143; called by muse, mutect2, varscan2
- IGKV1-16 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs1285620242; called by muse, varscan2
- IGKV4-1 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs139176691; called by muse, mutect2, varscan2
- IL1RAPL1 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV100150217; called by muse, mutect2, varscan2
- IL1RAPL2 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.929); catalogued as COSV100781913, COSV61160693, COSV61187040; called by muse, mutect2, varscan2
- ING5 | c.619-2A>T p.X207_splice | Splice Site (SNP) | VAF 61/273 reads (22%) | catalogued as COSV100546055; called by muse, mutect2, varscan2
- ITGA8 | c.1535C>G p.S512C | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); catalogued as rs1186004185, COSV100959708, COSV65235424; called by muse, mutect2, varscan2
- ITIH6 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99513933; called by muse, mutect2, varscan2
- JRK | c.212C>G p.S71C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.921); catalogued as COSV101401160, COSV70630644; called by muse, mutect2, varscan2
- KAT6A | c.4231G>C p.E1411Q | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.908); catalogued as COSV99705839; called by muse, mutect2, varscan2
- KCNK10 | c.445A>T p.S149C | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100069240; called by muse, mutect2, varscan2
- KIAA0825 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100266049; called by muse, mutect2, varscan2
- KLRF1 | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV54381124, COSV99684544; called by muse, mutect2, varscan2
- KRTAP10-7 | c.658A>T p.T220S | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs368037206; called by muse, mutect2
- KRTAP20-1 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | PolyPhen probably damaging (0.947); catalogued as COSV100228835, COSV58168161; called by muse, mutect2, varscan2
- KYNU | c.374-2A>G p.X125_splice | Splice Site (SNP) | VAF 11/41 reads (27%) | catalogued as rs893482697, COSV99933981; called by muse, mutect2, varscan2
- LDB2 | c.195A>T p.L65F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV100454732; called by muse, mutect2, varscan2
- LHFPL6 | c.450G>C p.Q150H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101095634; called by muse, mutect2, varscan2
- LILRB1 | c.2063C>T p.S688F (on ENST00000427581; = p.S637F on NM_006669.6) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs769871972, COSV100206733, COSV100207844; called by muse, mutect2, varscan2
- LILRB5 | c.1495G>A p.G499R (on ENST00000449561 / NM_001081442.3; = p.G498R on NM_006840.5) | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as COSV100300784, COSV100300815; called by muse, mutect2
- LMBR1L | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755182554, COSV57268280; called by muse, mutect2, varscan2
- LNP1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.294); catalogued as COSV101051360; called by muse, mutect2, varscan2
- LRFN5 | c.1148G>T p.S383I | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as COSV99985351; called by muse, mutect2, varscan2
- LRRC37A | c.4046G>A p.S1349N | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100208278; called by muse, mutect2
- LRRTM1 | c.310G>C p.V104L | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs748970613, COSV54441193, COSV99703120; called by muse, mutect2, varscan2
- MAGEA12 | c.388T>A p.F130I | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as COSV100757039; called by muse, mutect2, varscan2
- MAGEL2 | c.2711C>T p.A904V | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.22); catalogued as rs1423009238, COSV100046198; called by muse, mutect2, varscan2
- MAPRE3 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV99252013; called by muse, mutect2, varscan2
- MARCHF1 | c.552C>G p.I184M (on ENST00000274056; = p.I167M on NM_017923.4) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV99922493; called by muse, mutect2
- MIPOL1 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 17/98 reads (17%) | catalogued as COSV100539567; called by muse, mutect2, varscan2
- MOCOS | c.2039+1G>T p.X680_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99733890; called by muse, mutect2, varscan2
- MPDZ | c.3136G>T p.G1046C | Missense Mutation (SNP) | VAF 120/257 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100057485; called by muse, mutect2, varscan2
- MPPED1 | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs762503603, COSV100501330; called by muse, mutect2
- MSH3 | c.666C>G p.N222K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV99435620; called by muse, mutect2, varscan2
- MTR | c.743T>A p.V248E | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100856300; called by muse, mutect2, varscan2
- MUC17 | c.4394C>A p.T1465K | Missense Mutation (SNP) | VAF 81/382 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV100074961; called by muse, mutect2, varscan2
- MYADM | c.388C>A p.H130N | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.629); catalogued as COSV100425191; called by muse, mutect2, varscan2
- MYO3A | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 68/108 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770801976, COSV99781441; called by muse, mutect2, varscan2
- NALCN | c.3207G>C p.K1069N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV99215795, COSV99217538, COSV99218255; called by muse, mutect2, varscan2
- NEK11 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100797887; called by muse, mutect2
- NEXMIF | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV50205426; called by muse, mutect2, varscan2
- NFE2L1 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 31/118 reads (26%) | catalogued as COSV100671715; called by muse, mutect2, varscan2
- NLRP14 | c.1050G>A p.M350I | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100205418; called by muse, mutect2, varscan2
- NOS2 | c.885G>A p.W295* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100569880; called by muse, mutect2, varscan2
- NOX5 | c.1625G>C p.R542T | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV99534726; called by muse, mutect2, varscan2
- NR1H4 | c.1109-2A>T p.X370_splice (on ENST00000551379 / NM_001206993.2; = p.X356_splice on NM_005123.4) | Splice Site (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99501155; called by muse, mutect2
- NTN1 | c.1778A>G p.Q593R | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.683); catalogued as rs778747963, COSV99433751; called by muse, mutect2
- OR10A3 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV100660327; called by muse, mutect2, varscan2
- OR2A14 | c.576G>C p.W192C | Missense Mutation (SNP) | VAF 49/317 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.838); catalogued as COSV101376496; called by muse, mutect2, varscan2
- OR4C15 | c.460C>A p.L154I (on ENST00000314644; = p.L100I on NM_001001920.2) | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.159); catalogued as COSV100116081, COSV58951197, COSV58953684; called by muse, mutect2, varscan2
- OR4E2 | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100330152; called by muse, mutect2, varscan2
- OR52E6 | c.176A>T p.E59V | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV100259546; called by muse, mutect2, varscan2
- OR6K6 | c.329T>G p.L110R (on ENST00000368144; = p.L86R on NM_001005184.1) | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100933790; called by muse, mutect2, varscan2
- OR8K3 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV57133664; called by muse, mutect2, varscan2
- OS9 | c.575T>G p.V192G | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99233108; called by muse, mutect2, varscan2
- PAPOLA | c.1828C>T p.P610S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as COSV99354614; called by muse, mutect2, varscan2
- PAPPA2 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.229); catalogued as COSV100867122, COSV62775739, COSV62785967; called by muse, mutect2, varscan2
- PARP8 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs1421801606, COSV55866547, COSV99890149; called by muse, mutect2, varscan2
- PCDH1 | c.3380T>A p.F1127Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.058); catalogued as COSV99746929; called by muse, mutect2, varscan2
- PCDHB15 | c.1846G>T p.G616C | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99179179; called by muse, mutect2, varscan2
- PCDHB16 | c.1813C>A p.Q605K | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.132); catalogued as COSV99502817; called by muse, mutect2, varscan2
- PI4KA | c.6071A>G p.Y2024C | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1403366306, COSV99748457; called by muse, mutect2
- PRKD1 | c.2431G>C p.E811Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV100121469; called by muse, mutect2, varscan2
- PROX1 | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99800189; called by muse, mutect2
- PRRC2B | c.268A>T p.K90* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100622209; called by muse, mutect2, varscan2
- PRUNE2 | c.7036G>T p.E2346* | Nonsense Mutation (SNP) | VAF 33/172 reads (19%) | catalogued as COSV100945101; called by muse, mutect2, varscan2
- PXDN | c.1787C>G p.A596G | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1305003148, COSV99414818; called by muse, mutect2
- RARRES2 | c.286C>G p.R96G | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99784757; called by muse, varscan2
- RELN | c.3405G>T p.Q1135H | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1237253089, COSV100634888; called by muse, mutect2, varscan2
- RP1 | c.156G>T p.R52S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV99608780; called by muse, mutect2, varscan2
- RSPH3 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.275); catalogued as COSV99396548; called by muse, mutect2, varscan2
- RUSF1 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.345); catalogued as COSV100393404; called by muse, mutect2, varscan2
- SART1 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV56713915; called by muse, mutect2, varscan2
- SEMA6B | c.1406C>G p.S469C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); catalogued as COSV100015108; called by muse, mutect2, varscan2
- SFSWAP | c.2644C>G p.P882A | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV99906386; called by muse, mutect2
- SH2D3C | c.1033G>T p.V345F (on ENST00000314830 / NM_170600.3; = p.V188F on NM_005489.4) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.051); catalogued as COSV100137504, COSV59119642; called by muse, mutect2, varscan2
- SIT1 | c.187T>A p.L63M | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99425821; called by muse, mutect2, varscan2
- SLC6A5 | c.1153G>T p.G385W | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100117132; called by muse, mutect2, varscan2
- SOX13 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99690047; called by muse, mutect2, varscan2
- SPATA7 | c.1735G>C p.D579H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99247633; called by muse, mutect2, varscan2
- SPTA1 | c.5875G>T p.D1959Y | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935526, COSV63754222; called by muse, mutect2, varscan2
- SRFBP1 | c.403T>A p.S135T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.255); catalogued as COSV100232969; called by muse, mutect2, varscan2
- ST18 | c.1552A>T p.I518L | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99390958; called by muse, mutect2, varscan2
- STT3A | c.1672-2A>G p.X558_splice | Splice Site (SNP) | VAF 21/285 reads (7%) | catalogued as COSV101205279, COSV99074025; called by muse, mutect2
- SYNDIG1L | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV59047900; called by muse, mutect2, varscan2
- SYNE1 | c.20648G>A p.R6883H (on ENST00000367255 / NM_182961.4; = p.R6812H on NM_033071.3) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs758105121, COSV55024514; called by mutect2, varscan2
- SYPL2 | c.622T>A p.S208T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.824); catalogued as COSV100881581; called by muse, mutect2, varscan2
- TAAR1 | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV99257677, COSV99257746; called by muse, mutect2, varscan2
- TAAR6 | c.51C>A p.N17K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as COSV51582599; called by muse, mutect2, varscan2
- TAF1L | c.3916G>A p.V1306M | Missense Mutation (SNP) | VAF 95/232 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV99645366; called by muse, mutect2, varscan2
- TEX15 | c.7289A>T p.E2430V (on ENST00000256246; = p.E2813V on NM_001350162.2) | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as COSV56341986, COSV99822092; called by muse, mutect2, varscan2
- THSD1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs759689021, COSV99319064; called by muse, mutect2, varscan2
- TLL1 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1331379623, COSV50273525; called by muse, mutect2
- TMEM241 | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV101271780; called by muse, varscan2
- TNN | c.2149G>T p.D717Y | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV53421878, COSV53423613; called by muse, mutect2, varscan2
- TNXB | c.6490G>C p.D2164H (on ENST00000647633; = p.D1917H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100926619, COSV64483036, COSV64490962; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100709201; called by muse, mutect2, varscan2
- TRPC5 | c.1111A>T p.T371S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0.038); catalogued as COSV99462634; called by muse, mutect2, varscan2
- TRPM3 | c.3503G>A p.R1168Q (on ENST00000357533 / NM_001366142.2; = p.R1023Q on NM_020952.6) | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs764458021, COSV62580662; called by muse, mutect2, varscan2
- TTBK2 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1279529543, COSV99142425; called by muse, mutect2, varscan2
- TTC13 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV100793016; called by muse, mutect2, varscan2
- TTC14 | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99932352; called by muse, mutect2
- TTLL6 | c.1264G>A p.D422N (on ENST00000393382 / NM_001130918.3; = p.D115N on NM_173623.3) | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759548315, COSV100938222; called by muse, mutect2, varscan2
- TUBA3C | c.1246G>T p.G416W | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV101313882; called by muse, mutect2, varscan2
- USH2A | c.14516C>T p.T4839M | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs139065588, COSV56360228, COSV56383574; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- USP10 | c.2208A>T p.A736= | Splice Region (SNP) | VAF 21/83 reads (25%) | catalogued as COSV99551817; called by muse, mutect2, varscan2
- USP8 | c.2519G>A p.G840E | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100209271; called by muse, mutect2, varscan2
- UVRAG | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.084); catalogued as COSV100638623; called by muse, mutect2
- VPS13B | c.8659G>A p.E2887K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100663494; called by muse, varscan2
- WAPL | c.1991G>C p.G664A | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99556630; called by muse, mutect2
- WDR11 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV54788359, COSV99676967; called by muse, mutect2
- WDR64 | c.2887C>G p.L963V | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); catalogued as COSV100844023; called by muse, mutect2, varscan2
- WWC3 | c.2962T>A p.C988S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101081762; called by mutect2, varscan2
- ZMYM1 | c.2744G>C p.G915A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.35); catalogued as COSV100721062; called by muse, mutect2
- ZNF33A | c.1829G>A p.C610Y (on ENST00000458705 / NM_006974.3; = p.C611Y on NM_006954.2) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100276188; called by muse, mutect2, varscan2
- ZNF345 | c.253A>G p.T85A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV100080436; called by mutect2, varscan2
- ZNF521 | c.1577C>G p.S526C | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV100833331, COSV64129490; called by muse, mutect2
- ZNF536 | c.3422C>G p.S1141C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.293); catalogued as COSV100835820; called by muse, mutect2, varscan2
- ZNF565 | c.989G>A p.R330H (on ENST00000355114; = p.R290H on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs753655715, COSV100411998, COSV58410877; called by muse, mutect2, varscan2
- ZNF639 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 19/97 reads (20%) | catalogued as COSV58383669, COSV58384055; called by muse, mutect2, varscan2
- ZNF668 | c.1022G>A p.C341Y | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100336873; called by muse, mutect2, varscan2
- ZNF831 | c.1434C>G p.D478E | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.057); catalogued as COSV100926238; called by muse, mutect2, varscan2
- ZNF85 | c.1631G>A p.G544D | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.62); catalogued as COSV100060132; called by muse, mutect2, varscan2
- ZNRF3 | c.764C>A p.A255D (on ENST00000544604 / NM_001206998.2; = p.A155D on NM_032173.3) | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100238965; called by muse, mutect2, varscan2
- ZSWIM5 | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.824); catalogued as COSV100655789; called by muse, mutect2, varscan2
- DNAH8 | c.6010del p.Y2004Tfs*18 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- FAM222B | c.1322del p.P441Hfs*70 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- FOXD4L5 | c.115G>T p.V39L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by mutect2, varscan2
- NAA16 | c.369_383del p.Q124_R128del | In Frame Del (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- NR0B1 | c.999dup p.L334Tfs*55 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel
- SSTR1 | c.536dup p.V181Rfs*69 | Frame Shift Ins (INS) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- TLE1 | c.2178del p.T727Pfs*28 | Frame Shift Del (DEL) | VAF 13/97 reads (13%) | called by mutect2, pindel, varscan2
- TMEM200A | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by mutect2, varscan2
- TRGC1 | c.156C>A p.N52K | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.021); called by muse, mutect2
- XKR3 | c.304del p.W102Gfs*6 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- ZNF431 | c.444del p.A149Qfs*3 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, varscan2
- ZNF45 | c.1700G>T p.R567L | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- ABCA7 | c.810G>C p.L270= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV54037639, COSV99566613; called by muse, mutect2, varscan2
- ACOT11 | c.447C>T p.F149= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs772387844, COSV100650816, COSV59346499; called by muse, mutect2, varscan2
- ADAMTS15 | c.33C>T p.F11= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV54503944; called by muse, mutect2, varscan2
- ADARB1 | c.558G>A p.A186= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs146135960; called by muse, mutect2, varscan2
- ADCY3 | c.2247G>A p.E749= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99569082; called by muse, mutect2, varscan2
- AQP11 | c.342C>A p.P114= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV100547318; called by muse, mutect2, varscan2
- ARHGEF10 | c.2949G>C p.V983= (on ENST00000398564; = p.V958= on NM_014629.4) | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV100035560, COSV50645838; called by muse, mutect2
- ARX | c.135A>T p.G45= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100984082; called by mutect2, varscan2
- ATP13A3 | c.1023G>A p.V341= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs745613480, COSV99757622; called by muse, mutect2, varscan2
- BCAN | c.1290G>A p.T430= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as rs1302433204, COSV100228470; called by muse, mutect2, varscan2
- BCL6B | c.1434G>T p.G478= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs748524501, COSV53426694; called by muse, mutect2, varscan2
- BPIFB6 | c.138G>A p.K46= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV62754397; called by muse, mutect2, varscan2
- CAMK2D | c.1455G>A p.G485= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99594752; called by muse, mutect2, varscan2
- CFLAR | c.582C>T p.L194= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV57936980; called by muse, mutect2, varscan2
- CTNNA2 | c.540G>T p.G180= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100786055; called by muse, mutect2, varscan2
- CTNND2 | c.1758C>A p.A586= | Silent (SNP) | VAF 28/149 reads (19%) | catalogued as rs765074687, COSV100480785, COSV58898326; called by muse, mutect2, varscan2
- DIO3 | c.177C>G p.L59= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs371249251; called by muse, mutect2, varscan2
- DMD | c.8892C>G p.G2964= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100629177, COSV58956270; called by muse, mutect2
- EGFR | c.837G>A p.V279= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV99294763; called by muse, mutect2
- ELF2 | c.1284G>A p.A428= (on ENST00000379550 / NM_001331036.2; = p.A368= on NM_006874.4) | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs770543967, COSV99642485; called by muse, mutect2, varscan2
- EYA4 | c.1104G>T p.P368= (on ENST00000531901 / NM_001301013.1; = p.P362= on NM_004100.5) | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV100766317; called by muse, mutect2, varscan2
- FAM135B | c.1458G>A p.V486= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV99427281; called by muse, mutect2
- FAM13A | c.2355G>T p.A785= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as COSV99984637, COSV99985034; called by muse, mutect2, varscan2
- FBXO3 | c.1059A>G p.P353= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99682326; called by muse, mutect2, varscan2
- FLT4 | c.258C>T p.G86= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs1197145113, COSV99988867; called by muse, mutect2, varscan2
- FRZB | c.66C>T p.L22= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV54553859, COSV99717544; called by muse, mutect2, varscan2
- FUT9 | c.696T>C p.I232= | Silent (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- GPM6A | c.516T>C p.N172= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV99705511; called by muse, mutect2, varscan2
- GUCA1A | c.432C>T p.D144= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as rs1263382505, COSV50003478; called by muse, mutect2, varscan2
- H2AC13 | c.270C>T p.N90= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs766005373, COSV100704439; called by muse, mutect2, varscan2
- HEATR5B | c.5634C>G p.V1878= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99250188; called by muse, mutect2, varscan2
- HTR1A | c.1182G>T p.L394= | Silent (SNP) | VAF 50/216 reads (23%) | catalogued as COSV100109061, COSV100109266; called by muse, mutect2, varscan2
- HTR1A | c.624G>T p.L208= | Silent (SNP) | VAF 41/168 reads (24%) | catalogued as COSV100109268; called by muse, mutect2, varscan2
- HYAL4 | c.1179C>T p.N393= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs758539563, COSV56139184; called by muse, mutect2, varscan2
- IER5 | c.441G>C p.P147= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100849704; called by muse, mutect2
- IGSF22 | c.654G>T p.L218= | Silent (SNP) | VAF 20/181 reads (11%) | catalogued as COSV100080354; called by muse, mutect2, varscan2
- ITGAL | c.2463G>C p.L821= | Silent (SNP) | VAF 33/224 reads (15%) | catalogued as rs761843928, COSV100776342; called by muse, mutect2, varscan2
- KAT6A | c.2661C>G p.L887= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV55912663, COSV99705840; called by muse, mutect2, varscan2
- KCNK18 | c.810T>C p.D270= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV100572130; called by muse, mutect2, varscan2
- LINGO2 | c.192C>T p.L64= | Silent (SNP) | VAF 73/171 reads (43%) | catalogued as COSV100431184; called by muse, mutect2, varscan2
- MS4A5 | c.579T>C p.D193= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as rs199735850; called by muse, mutect2, varscan2
- MTMR3 | c.1518G>A p.Q506= | Silent (SNP) | VAF 45/177 reads (25%) | catalogued as COSV100071335; called by muse, mutect2, varscan2
- MUC16 | c.30873C>T p.T10291= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs1384826187, COSV101201476; called by muse, mutect2, varscan2
- NPAS3 | c.243T>A p.P81= (on ENST00000356141 / NM_001164749.2; = p.P51= on NM_022123.3) | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV100389795; called by muse, mutect2, varscan2
- OR2D2 | c.255G>T p.L85= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100203925; called by muse, mutect2, varscan2
- OR4D11 | c.726C>T p.S242= | Silent (SNP) | VAF 30/201 reads (15%) | catalogued as COSV57586626; called by muse, mutect2, varscan2
- OR51G1 | c.96C>A p.P32= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV100429409; called by muse, mutect2, varscan2
- OR8B2 | c.910C>T p.L304= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100899500, COSV66665594; called by muse, mutect2, varscan2
- OSBPL6 | c.2628G>A p.E876= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as rs369599097; called by muse, mutect2, varscan2
- P2RX3 | c.729C>T p.I243= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV54443140, COSV54443283; called by mutect2, varscan2
- PARD3 | c.3471G>C p.L1157= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100633216; called by muse, varscan2
- PCDH10 | c.3075G>T p.T1025= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as COSV99993586, COSV99994447; called by muse, mutect2
- PCDHB16 | c.546C>T p.I182= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs377183903; called by muse, mutect2, varscan2
- PIK3R4 | c.468C>T p.V156= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV100768591; called by muse, mutect2, varscan2
- PNOC | c.252C>T p.L84= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100108398, COSV57284584; called by muse, mutect2, varscan2
- POU1F1 | c.103C>T p.L35= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV100622772; called by muse, varscan2
- PRSS58 | c.594G>A p.P198= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs773633290, COSV73488763; called by muse, mutect2, varscan2
- RAB11FIP2 | c.1335T>A p.T445= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV100843123; called by muse, mutect2, varscan2
- RILPL1 | c.345G>A p.E115= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100971372; called by muse, mutect2, varscan2
- RPL3L | c.858C>G p.R286= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99238482; called by muse, mutect2, varscan2
- RYR3 | c.922C>A p.R308= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV101214403, COSV66779580; called by muse, varscan2
- SEPTIN4 | c.1128C>G p.T376= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100400440; called by muse, mutect2, varscan2
- SLC7A3 | c.1404C>T p.I468= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs1465813695, COSV99979842; called by muse, mutect2, varscan2
- SSTR1 | c.1086C>A p.A362= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV57457748; called by muse, mutect2, varscan2
- TEP1 | c.4465C>T p.L1489= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as COSV52993884, COSV52995876; called by muse, mutect2, varscan2
- TMEM200A | c.675C>G p.S225= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV99760060; called by muse, mutect2, varscan2
- TRIM45 | c.1485G>C p.V495= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99868718; called by muse, mutect2
- TSNARE1 | c.663C>A p.L221= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100211441; called by muse, mutect2, varscan2
- TTC8 | c.228A>G p.Q76= (on ENST00000338104 / NM_001288781.1; = p.Q86= on NM_144596.4) | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100581640, COSV57628188; called by muse, mutect2, varscan2
- TTN | c.24984C>T p.F8328= (on ENST00000591111; = p.F7401= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV60361401; called by muse, mutect2, varscan2
- UGCG | c.150C>T p.L50= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV100959001; called by muse, mutect2, varscan2
- VPS13B | c.8586G>A p.E2862= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV100663492; called by muse, varscan2
- WSCD2 | c.129C>T p.P43= | Silent (SNP) | VAF 30/176 reads (17%) | catalogued as rs766938229, COSV54578097; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1347A>G p.L449= | Silent (SNP) | VAF 61/252 reads (24%) | catalogued as COSV100460366; called by muse, mutect2, varscan2
- ZNF136 | c.297G>A p.V99= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV59712188; called by muse, mutect2, varscan2
- ABCA1 | c.720+2687G>C | Intron (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101037595; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83370A>G | Intron (SNP) | VAF 49/225 reads (22%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847733 T>C | 5'Flank (SNP) | VAF 13/37 reads (35%) | catalogued as rs1172838648; called by muse, mutect2, varscan2
- BTN2A3P | n.1448-366C>G | Intron (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- DEPDC5 | c.1870+2384G>A | Intron (SNP) | VAF 27/260 reads (10%) | catalogued as COSV99836493; called by muse, mutect2, varscan2
- PCDH11X | c.3033+30C>G | Intron (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100014982; called by muse, mutect2
